Somatic mutation profile of tumor specimen MP2PRT-PAPBYT-TMP1-A (aliquot MP2PRT-PAPBYT-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPBYT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,123 days).
Specimen MP2PRT-PAPBYT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e50077e3-2a6c-4eaa-ad63-04369d07d9d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPBYT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPBYT-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b657ab1-bd50-4292-bcdf-9f2074406a5b

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, 5'UTR 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXorf21 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 11/313 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100973378, COSV100973382; called by muse, mutect2
- DNAH10 | c.8197G>A p.E2733K (on ENST00000409039; = p.E2672K on NM_207437.3) | Missense Mutation (SNP) | VAF 35/381 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs770315329, COSV101292481; called by muse, mutect2
- FASN | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 35/676 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs756471902, COSV100147502; called by muse, mutect2
- GRM1 | c.3301G>C p.E1101Q | Missense Mutation (SNP) | VAF 50/613 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.989); catalogued as COSV99265170; called by muse, mutect2
- MAP2 | c.2616C>G p.F872L | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1415794114; called by muse, mutect2
- SETBP1 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 77/298 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as rs774075566, COSV56313636; called by muse, mutect2, varscan2
- SPAM1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141109529; called by muse, mutect2
- VNN3 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 31/385 reads (8%) | catalogued as rs767213147; called by muse, mutect2
- ANKS3 | c.186G>C p.L62F | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BTBD2 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2
- CABYR | c.941A>T p.E314V | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- FAT3 | c.4259del p.P1420Lfs*12 | Frame Shift Del (DEL) | VAF 58/376 reads (15%) | called by mutect2, pindel, varscan2
- SHANK3 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 17/592 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CATSPERG | c.1338C>G p.L446= | Silent (SNP) | VAF 20/429 reads (5%) | called by muse, mutect2
- CDCP2 | c.1350C>T p.A450= | Silent (SNP) | VAF 27/538 reads (5%) | catalogued as rs559556566; called by muse, mutect2
- CKMT2 | c.591G>A p.E197= | Silent (SNP) | VAF 23/678 reads (3%) | catalogued as rs1404998941; called by muse, mutect2
- PCDH11Y | c.2157G>A p.P719= (on ENST00000400457 / NM_032973.2; = p.P708= on NM_032971.3) | Silent (SNP) | VAF 40/221 reads (18%) | called by muse, mutect2, varscan2
- PEDS1 | c.111C>G p.L37= | Silent (SNP) | VAF 31/550 reads (6%) | called by muse, mutect2
- SLIT1 | c.1671C>A p.A557= | Silent (SNP) | VAF 123/288 reads (43%) | called by muse, mutect2, varscan2
- TCN2 | c.759C>T p.L253= | Silent (SNP) | VAF 62/210 reads (30%) | catalogued as rs1168382538; called by muse, mutect2, varscan2
- AL390726.5 | n.562C>T | RNA (SNP) | VAF 35/436 reads (8%) | called by muse, mutect2
- TENT5A | c.-9G>C | 5'UTR (SNP) | VAF 130/799 reads (16%) | catalogued as rs865843852; called by muse, mutect2, varscan2
